Somatic mutation profile of tumor specimen TCGA-62-A472-01A (aliquot TCGA-62-A472-01A-11D-A24D-08) from TCGA case TCGA-62-A472, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 70.9 years (25,893 days).
Specimen TCGA-62-A472-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4f0437f4-be61-4881-8f74-fe88e4cc4ed3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-62-A472-10A (Blood Derived Normal), aliquot TCGA-62-A472-10A-01D-A24F-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/050b0844-ba9b-4257-8f83-f68f054f67ab

The open-access MAF lists 63 somatic variants for this specimen: 47 protein-altering or splice-affecting, 16 silent.
By variant classification: Missense Mutation 38, Silent 16, Frame Shift Del 5, Nonsense Mutation 3, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ACTR2 | c.269A>G p.D90G | Missense Mutation (SNP) | VAF 28/111 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.639); catalogued as COSV99573711; called by muse, mutect2, varscan2
- ADAMTSL3 | c.735A>C p.E245D | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated (0.96); PolyPhen probably damaging (0.978); catalogued as COSV99717018; called by muse, mutect2, varscan2
- AGAP4 | c.1271A>C p.Q424P | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.582); catalogued as COSV101432605; called by mutect2, varscan2
- ANKRD39 | c.197C>T p.T66I | Missense Mutation (SNP) | VAF 31/177 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as rs773816799, COSV101135515; called by muse, mutect2, varscan2
- ANTXR1 | c.1040G>T p.C347F | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100361913; called by muse, mutect2, varscan2
- BMS1 | c.3169G>A p.E1057K | Missense Mutation (SNP) | VAF 26/114 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.589); catalogued as rs1388020507, COSV65733208; called by muse, mutect2, varscan2
- CACNA1I | c.2047T>G p.F683V | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100359267; called by muse, mutect2, varscan2
- CACNA2D2 | c.477del p.I159Mfs*29 | Frame Shift Del (DEL) | VAF 5/34 reads (15%) | catalogued as COSV56568825; called by mutect2, pindel
- CCDC127 | c.539G>T p.R180L | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57257390, COSV99722883; called by muse, mutect2, varscan2
- CCT8L2 | c.1385A>T p.D462V | Missense Mutation (SNP) | VAF 41/107 reads (38%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.686); catalogued as COSV100742565; called by muse, mutect2, varscan2
- DENND4B | c.4488C>G p.C1496W | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.298); catalogued as COSV100768414; called by muse, varscan2
- DERA | c.127C>T p.Q43* | Nonsense Mutation (SNP) | VAF 3/25 reads (12%) | catalogued as COSV101397282; called by muse, mutect2
- FARS2 | c.7G>T p.G3C | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV99212906; called by muse, mutect2, varscan2
- FOXD4L5 | c.821C>T p.S274L | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.026); catalogued as rs1025870625, COSV101073020, COSV101073276; called by muse, mutect2, varscan2
- GRID2 | c.2909C>G p.P970R | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as COSV99937488; called by muse, mutect2
- H2BC5 | c.313G>C p.G105R | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.419); catalogued as COSV99175214, COSV99175335; called by muse, mutect2, varscan2
- IQGAP2 | c.1444A>G p.N482D | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT tolerated (0.36); PolyPhen benign (0.012); catalogued as COSV99166718; called by muse, mutect2, varscan2
- ITK | c.1547C>A p.T516K | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT tolerated (0.5); PolyPhen benign (0.015); catalogued as COSV101439636; called by muse, mutect2, varscan2
- KDM3A | c.806G>A p.G269E | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.41); PolyPhen benign (0.012); catalogued as rs974051983, COSV57226295; called by muse, mutect2, varscan2
- LAMP1 | c.542A>G p.N181S | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated (0.21); PolyPhen benign (0.057); catalogued as rs1210069640, COSV100208502; called by muse, mutect2, varscan2
- MAP1A | c.2996C>G p.P999R | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV100288102; called by muse, mutect2, varscan2
- MUC6 | c.178G>A p.V60M | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.067); catalogued as rs748948615, COSV101424399; called by muse, mutect2, varscan2
- OR1L8 | c.209C>G p.T70S | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.071); catalogued as COSV100508413; called by muse, mutect2, varscan2
- OR2A2 | c.538A>T p.I180F | Missense Mutation (SNP) | VAF 54/157 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.443); catalogued as COSV101286618; called by muse, mutect2, varscan2
- OR4C16 | c.765G>A p.M255I | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs776318259, COSV100113847; called by muse, mutect2, varscan2
- OR51T1 | c.674G>A p.R225H | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT tolerated (0.33); PolyPhen benign (0.039); catalogued as rs144368286; called by muse, mutect2
- PCDH10 | c.2891G>T p.R964L | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.987); catalogued as rs142202092; called by muse, mutect2, varscan2
- PRKG2 | c.634C>T p.R212* | Nonsense Mutation (SNP) | VAF 14/50 reads (28%) | catalogued as COSV52328136; called by muse, mutect2, varscan2
- PSG5 | c.4G>A p.G2R | Missense Mutation (SNP) | VAF 30/114 reads (26%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.897); catalogued as COSV100742562; called by muse, mutect2, varscan2
- QSOX2 | c.1039G>A p.G347R | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs369920025, COSV100699747; called by muse, mutect2, varscan2
- RACGAP1 | c.1083G>A p.M361I | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.234); catalogued as COSV100407543; called by mutect2, varscan2
- ST18 | c.455G>T p.S152I | Missense Mutation (SNP) | VAF 40/155 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.178); catalogued as COSV99388268; called by muse, mutect2, varscan2
- TNRC6C | c.2754C>A p.N918K | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.687); catalogued as COSV100049481; called by muse, mutect2, varscan2
- TP53 | c.657del p.Y220Mfs*27 | Frame Shift Del (DEL) | VAF 7/19 reads (37%) | catalogued as COSV52965002, COSV53107694, COSV53515706; called by mutect2, pindel, varscan2
- TRIM38 | c.625C>A p.L209M | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV100837533; called by muse, mutect2, varscan2
- TUBAL3 | c.1075A>T p.K359* | Nonsense Mutation (SNP) | VAF 13/39 reads (33%) | catalogued as COSV100990467; called by muse, mutect2, varscan2
- UMODL1 | c.3950A>G p.Y1317C (on ENST00000408910 / NM_001004416.2; = p.Y1445C on NM_173568.3) | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.628); catalogued as COSV101252477; called by muse, mutect2, varscan2
- WDR90 | c.3013G>A p.D1005N | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs1328528443, COSV99552714; called by muse, mutect2, varscan2
- XXYLT1 | c.988G>T p.D330Y | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100118078; called by muse, mutect2, varscan2
- ZNF169 | c.811T>A p.F271I | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100566137; called by muse, mutect2, varscan2
- ZNF479 | c.676T>C p.S226P | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.347); catalogued as COSV100482488; called by muse, mutect2
- ZYG11B | c.575A>T p.D192V | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99596846; called by muse, mutect2, varscan2
- CRISPLD1 | c.127del p.D43Mfs*6 | Frame Shift Del (DEL) | VAF 50/168 reads (30%) | called by mutect2, pindel, varscan2
- KCNS2 | c.1264_1270del p.Q422Rfs*13 | Frame Shift Del (DEL) | VAF 32/218 reads (15%) | called by mutect2, pindel, varscan2
- TIGAR | c.524dup p.N175Kfs*5 | Frame Shift Ins (INS) | VAF 10/76 reads (13%) | called by pindel, varscan2
- TWNK | c.964_982del p.A322Nfs*19 | Frame Shift Del (DEL) | VAF 21/95 reads (22%) | called by mutect2, pindel, varscan2
- ARHGAP26 | c.1770C>T p.D590= | Silent (SNP) | VAF 45/143 reads (31%) | catalogued as COSV99189164; called by muse, mutect2, varscan2
- BNC2 | c.1683T>G p.S561= | Silent (SNP) | VAF 24/59 reads (41%) | catalogued as rs777240994, COSV101032203; called by muse, mutect2, varscan2
- CALHM5 | c.810T>A p.S270= | Silent (SNP) | VAF 21/83 reads (25%) | catalogued as COSV100635519; called by muse, mutect2, varscan2
- CCBE1 | c.948T>G p.S316= | Silent (SNP) | VAF 49/131 reads (37%) | catalogued as COSV101232773; called by muse, mutect2, varscan2
- CEP250 | c.2253C>T p.D751= | Silent (SNP) | VAF 21/126 reads (17%) | catalogued as rs778073765, COSV100698746; called by muse, mutect2, varscan2
- H2BC5 | c.312G>T p.P104= | Silent (SNP) | VAF 31/80 reads (39%) | catalogued as COSV56800370, COSV99175213; called by muse, mutect2, varscan2
- HIPK1 | c.2589C>T p.S863= | Silent (SNP) | VAF 20/115 reads (17%) | catalogued as rs1257904426, COSV100478452; called by muse, mutect2, varscan2
- HOXD3 | c.228G>A p.L76= | Silent (SNP) | VAF 11/62 reads (18%) | catalogued as rs1267889049, COSV99979899; called by muse, mutect2, varscan2
- IGSF1 | c.963C>A p.P321= | Silent (SNP) | VAF 13/25 reads (52%) | catalogued as COSV63839326; called by muse, mutect2, varscan2
- IVNS1ABP | c.267T>C p.Y89= | Silent (SNP) | VAF 10/43 reads (23%) | catalogued as COSV100832493; called by muse, mutect2, varscan2
- KCNJ11 | c.823C>T p.L275= | Silent (SNP) | VAF 15/106 reads (14%) | catalogued as COSV100378987; called by muse, mutect2, varscan2
- KMT2D | c.1524A>G p.E508= | Silent (SNP) | VAF 19/55 reads (35%) | catalogued as rs923799631, COSV99977701; called by muse, mutect2, varscan2
- MMP8 | c.54C>A p.S18= | Silent (SNP) | VAF 17/144 reads (12%) | catalogued as COSV99368167; called by muse, mutect2
- MTERF1 | c.1048C>A p.R350= | Silent (SNP) | VAF 20/57 reads (35%) | catalogued as COSV100699540, COSV61099031; called by muse, mutect2, varscan2
- TMEM72 | c.465C>T p.S155= | Silent (SNP) | VAF 30/149 reads (20%) | catalogued as rs768619195, COSV67460255; called by muse, mutect2, varscan2
- TPK1 | c.120T>A p.L40= | Silent (SNP) | VAF 29/134 reads (22%) | catalogued as COSV100765328; called by muse, mutect2, varscan2
